Gene-level copy-number profile of tumor specimen TCGA-23-2078-01A from TCGA case TCGA-23-2078, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 66.3 years (24,223 days).
Specimen TCGA-23-2078-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.71ed9464-f906-4796-9993-2662d32bf372.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-2078-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e98ce47a-80b3-4a51-9fd9-e53d6c52758d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 16,225; copy number 2: 34,528; copy number 3: 7,519; copy number 4: 1,523; copy number 5: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-2078-01A-01D-0663-01): tumor purity 0.6, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:24,157,835–25,648,104, 21 genes: NUP35P1, AC063961.1, MIR603, AL356113.1, AL353583.1, ARHGAP21, RNA5SP305, AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:77,567,508–77,811,844, 2 genes, copy number 5: AC133040.1, RNU6-217P.

Autosomal genes at a single copy (total copy number 1): 13,805. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
